Somatic mutation profile of tumor specimen TCGA-D3-A51T-06A (aliquot TCGA-D3-A51T-06A-11D-A25O-08) from TCGA case TCGA-D3-A51T, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.8 years (21,857 days).
Specimen TCGA-D3-A51T-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9116282a-4003-45b7-90ff-12db49151dd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A51T-10A (Blood Derived Normal), aliquot TCGA-D3-A51T-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f786a24b-9728-4b6d-83fc-b3aad3a634a2

The open-access MAF lists 1,423 somatic variants for this specimen: 924 protein-altering or splice-affecting, 468 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 831, Silent 468, Nonsense Mutation 66, Splice Region 13, Intron 13, RNA 11, Splice Site 9, Frame Shift Ins 3, 5'UTR 2, 3'Flank 2, Translation Start Site 2, 5'Flank 2.

Variants (750 of 1,423; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1525G>A p.G509R (on ENST00000288602 / NM_001374244.1; = p.G469R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs121913357, BM1457681, COSV56070557, COSV56082352, COSV99953015; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HGF | c.495G>A p.S165= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs137853235, CS094308, COSV55948710; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IGHM | c.777G>A p.W259* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as rs281865422; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 18/26 reads (69%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.523A>T p.I175F | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59391519; called by muse, mutect2, varscan2
- ABCA2 | c.5155C>T p.R1719C (on ENST00000614293; = p.R1689C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs373639242, COSV55805617; called by muse, mutect2, varscan2
- ABCA6 | c.3680G>A p.R1227Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs768418765, COSV52636930; called by muse, mutect2, varscan2
- ABCC10 | c.673T>A p.S225T (on ENST00000372530 / NM_001198934.2; = p.S182T on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV55092941; called by muse, mutect2, varscan2
- ABCF3 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.737); catalogued as COSV53054285, COSV99491734; called by muse, mutect2, varscan2
- AC098582.1 | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.358); catalogued as COSV52018075, COSV52023845; called by muse, mutect2, varscan2
- AC126283.2 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.189); catalogued as COSV67099653; called by muse, mutect2, varscan2
- ACACB | c.5441C>T p.S1814F | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs920176873, COSV58143864; called by muse, mutect2, varscan2
- ACBD7 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62252816; called by muse, mutect2, varscan2
- ACE | c.2776G>A p.D926N | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV52012238; called by muse, mutect2, varscan2
- ACHE | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1399916623, COSV53816542; called by muse, mutect2, varscan2
- ACOT12 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.127); catalogued as rs372168909, COSV56897464; called by muse, mutect2, varscan2
- ACY3 | c.497A>G p.N166S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV54830037; called by muse, mutect2, varscan2
- ADAM11 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV52349321; called by muse, mutect2, varscan2
- ADAM15 | c.747C>T p.F249= | Splice Region (SNP) | VAF 16/54 reads (30%) | catalogued as COSV55125821, COSV55126633; called by muse, mutect2, varscan2
- ADAM18 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55853484; called by muse, mutect2, varscan2
- ADAM29 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV63667294; called by muse, mutect2, varscan2
- ADAMTS18 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs1199058022, COSV51421765; called by muse, mutect2, varscan2
- ADAMTS19 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV50787054; called by muse, mutect2, varscan2
- ADAMTS19 | c.3467A>T p.N1156I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50787121; called by muse, mutect2, varscan2
- ADAMTS6 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.199); catalogued as COSV66859441, COSV66863755; called by muse, mutect2, varscan2
- ADAMTS6 | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); catalogued as COSV66863759, COSV66864899; called by muse, mutect2, varscan2
- ADGRG4 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV54954382, COSV54964615; called by muse, mutect2, varscan2
- ADGRG4 | c.5456C>T p.S1819L | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54961481, COSV99796359; called by muse, mutect2, varscan2
- ADGRL2 | c.3226C>T p.Q1076* (on ENST00000370717 / NM_001366005.1; = p.Q1063* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV54684132; called by muse, mutect2, varscan2
- AFAP1L2 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100412334; called by muse, mutect2, varscan2
- AFF2 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as rs1557256430, COSV60664395, COSV60668509; called by muse, mutect2, varscan2
- AFF3 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as COSV57863953, COSV57869256; called by muse, mutect2, varscan2
- AGT | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1319418379, COSV64185400; called by muse, mutect2, varscan2
- AKAP9 | c.6454G>A p.E2152K (on ENST00000359028; = p.E2120K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62355720; called by muse, mutect2, varscan2
- AKR1B10 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV62056424; called by muse, mutect2, varscan2
- AKR1C8P | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782467293; called by muse, mutect2, varscan2
- AKT1S1 | c.497C>T p.T166I (on ENST00000344175 / NM_001098633.4; = p.T186I on NM_032375.5) | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV59277538; called by muse, mutect2, varscan2
- ALDH2 | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55670582; called by muse, mutect2, varscan2
- ALG10 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56791585; called by muse, mutect2, varscan2
- ALG13 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV52643999; called by muse, mutect2, varscan2
- ALPK1 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1350903610, COSV51590524; called by muse, mutect2, varscan2
- AMBRA1 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54061098; called by muse, mutect2, varscan2
- AMELX | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.196); catalogued as rs760321133, CD023227, COSV61634124; called by muse, mutect2, varscan2
- AMY2B | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV63716776; called by muse, mutect2, varscan2
- ANK1 | c.3044C>T p.S1015F | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55878871; called by muse, mutect2, varscan2
- ANK2 | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs144113099; called by muse, mutect2, varscan2
- ANK3 | c.6853G>A p.D2285N | Missense Mutation (SNP) | VAF 49/65 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55064792; called by muse, mutect2, varscan2
- ANKRD45 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs760394216, COSV60962333; called by muse, mutect2, varscan2
- ANPEP | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.46); catalogued as COSV55590732; called by muse, mutect2, varscan2
- APBB1IP | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV63302092; called by muse, mutect2, varscan2
- APOB | c.3304A>T p.T1102S | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.997); catalogued as COSV51948969; called by muse, mutect2, varscan2
- ARHGAP21 | c.5498C>A p.S1833* | Nonsense Mutation (SNP) | VAF 18/25 reads (72%) | catalogued as COSV57610101; called by muse, mutect2, varscan2
- ARHGAP29 | c.2882G>A p.G961E | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867918256, COSV53110801; called by muse, mutect2, varscan2
- ARHGAP29 | c.2389A>G p.N797D | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.41); catalogued as COSV53115861; called by muse, mutect2, varscan2
- ARHGAP35 | c.3304G>A p.E1102K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV68334366, COSV68334853; called by muse, mutect2, varscan2
- ARHGAP4 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63133881; called by muse, mutect2, varscan2
- ARHGAP6 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.714); catalogued as COSV61634129; called by muse, mutect2, varscan2
- ARHGEF5 | c.4669G>A p.E1557K | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50217138; called by muse, mutect2, varscan2
- ARHGEF6 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.066); catalogued as COSV51695123; called by muse, mutect2, varscan2
- ARMC4 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV53463031; called by muse, mutect2, varscan2
- ARMCX3 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | catalogued as COSV57871454; called by muse, mutect2, varscan2
- ARRDC2 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55844403; called by muse, mutect2, varscan2
- ASPG | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV71934083; called by mutect2, varscan2
- ASPM | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs750028073, COSV54136796; called by muse, mutect2, varscan2
- ASXL3 | c.3092C>T p.S1031F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as rs375247575; called by muse, mutect2, varscan2
- ATCAY | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56658496; called by muse, mutect2, varscan2
- ATG14 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as rs940692566, COSV55956070; called by muse, mutect2, varscan2
- ATM | c.7577G>A p.R2526K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs876659323, COSV53761590, COSV53776853; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATOH1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs1445463184, COSV60038610; called by muse, mutect2, varscan2
- ATP10B | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58778866, COSV58780832; called by muse, mutect2, varscan2
- ATP2B2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as rs766306375, COSV59488988; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1856C>T p.S619F | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as rs1274101552, COSV52875244; called by muse, mutect2, varscan2
- ATRNL1 | c.2890C>T p.P964S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs781958925, COSV58110096; called by muse, mutect2, varscan2
- ATXN10 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.603); catalogued as rs1441368577, COSV53299995; called by muse, mutect2, varscan2
- AVIL | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99142243; called by muse, mutect2, varscan2
- B4GALNT4 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV57325870; called by muse, mutect2, varscan2
- BCORL1 | c.4913T>C p.I1638T | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV54404717; called by muse, mutect2, varscan2
- BEGAIN | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.997); catalogued as COSV62069941; called by muse, mutect2, varscan2
- BEND4 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.16); catalogued as rs771898046, COSV72468916, COSV72469273; called by muse, mutect2, varscan2
- BMP1 | c.2875C>T p.H959Y | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.264); catalogued as COSV60534136; called by muse, mutect2, varscan2
- BNC1 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.354); catalogued as COSV61758841; called by muse, mutect2, varscan2
- BPIFC | c.324C>G p.N108K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.902); catalogued as COSV55915268; called by muse, mutect2, varscan2
- BRINP3 | c.1491G>A p.M497I | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV66516979, COSV66528956; called by muse, mutect2, varscan2
- BRMS1L | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); catalogued as COSV53764314; called by muse, mutect2, varscan2
- BTK | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58123080; called by muse, mutect2, varscan2
- C11orf53 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as rs369356034, COSV54721419; called by muse, mutect2, varscan2
- C12orf56 | c.1579C>T p.P527S (on ENST00000543942 / NM_001170633.2; = p.P367S on NM_001099676.3) | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV61489579; called by muse, mutect2, varscan2
- C14orf39 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58781114, COSV58784447; called by muse, mutect2, varscan2
- C1QB | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs754513747, COSV59245456; called by muse, mutect2, varscan2
- C1orf162 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); catalogued as COSV59059617; called by muse, mutect2, varscan2
- CA2 | c.133A>G p.K45E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV53407996; called by muse, mutect2, varscan2
- CACNA1C | c.700A>T p.K234* | Nonsense Mutation (SNP) | VAF 62/177 reads (35%) | catalogued as COSV59760554; called by muse, mutect2, varscan2
- CACNA1D | c.4957G>A p.E1653K (on ENST00000350061 / NM_001128840.3; = p.E1673K on NM_000720.4) | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV55461529; called by muse, mutect2, varscan2
- CACNA1G | c.5750C>T p.S1917L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV61736043; called by muse, mutect2, varscan2
- CACNA2D3 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 9/14 reads (64%) | catalogued as rs1351986488, COSV55572961; called by muse, mutect2, varscan2
- CACNA2D3 | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55572973; called by muse, mutect2, varscan2
- CACNG6 | c.671G>A p.G224D (on ENST00000252729 / NM_145814.1; = p.G153D on NM_031897.2) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53165805; called by muse, mutect2, varscan2
- CADPS | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1439217349, COSV51898164; called by muse, mutect2, varscan2
- CAMK2B | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs757988232, COSV51665233; called by mutect2, varscan2
- CAPZB | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 84/240 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); catalogued as COSV51651105; called by muse, mutect2, varscan2
- CASC3 | c.1751G>A p.G584D | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99229576; called by muse, mutect2, varscan2
- CBS | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV61445029; called by muse, mutect2, varscan2
- CBX4 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 111/213 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV53966363, COSV53967272; called by muse, mutect2, varscan2
- CCDC191 | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.97); PolyPhen benign (0.014); catalogued as COSV55675487; called by muse, mutect2, varscan2
- CCDC33 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58356842; called by muse, mutect2, varscan2
- CCDC68 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs372995837, COSV61604648; called by muse, mutect2
- CCDC81 | c.1660G>T p.D554Y (on ENST00000445632 / NM_001156474.2; = p.D464Y on NM_021827.4) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV53580955; called by muse, mutect2
- CCDC87 | c.2123A>G p.K708R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV59580267; called by muse, mutect2, varscan2
- CCL11 | c.239G>A p.W80* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV59925579; called by muse, mutect2, varscan2
- CCNT2 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51475889; called by muse, mutect2, varscan2
- CCT8L2 | c.960G>A p.W320* | Nonsense Mutation (SNP) | VAF 57/136 reads (42%) | catalogued as COSV63463603; called by muse, mutect2, varscan2
- CD163L1 | c.3917G>A p.G1306E | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484430669, COSV58015119, COSV58023097; called by muse, mutect2, varscan2
- CD209 | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52657801; called by muse, mutect2, varscan2
- CD53 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54761335; called by muse, mutect2, varscan2
- CDCA4 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as COSV60316042; called by muse, mutect2, varscan2
- CDH4 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV64641612, COSV64643972; called by muse, mutect2, varscan2
- CDH5 | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1487892645, COSV58519484; called by muse, mutect2, varscan2
- CDH5 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58519902; called by muse, mutect2, varscan2
- CDH7 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs751741132, COSV59883604; called by muse, mutect2, varscan2
- CDH9 | c.2246C>T p.S749L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1161575895, COSV50265477; called by muse, mutect2, varscan2
- CDHR2 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56143930; called by muse, mutect2, varscan2
- CDK7 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV56515391; called by muse, mutect2, varscan2
- CDKL3 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV99527721; called by mutect2, varscan2
- CDO1 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99164759; called by muse, mutect2, varscan2
- CDSN | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs775263614, COSV99456740; called by muse, mutect2, varscan2
- CELSR1 | c.2768C>T p.P923L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as COSV53097962; called by muse, mutect2, varscan2
- CENPJ | c.3878C>T p.A1293V | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV55048835; called by muse, mutect2, varscan2
- CERS6 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59834500; called by muse, mutect2, varscan2
- CETN1 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as rs143489830, COSV59121030; called by muse, mutect2, varscan2
- CFAP251 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293132177, COSV56614779; called by muse, mutect2, varscan2
- CFAP47 | c.2595G>A p.M865I | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52880585; called by muse, mutect2, varscan2
- CFAP47 | c.4318G>A p.D1440N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.625); catalogued as COSV57975517, COSV57976132; called by muse, mutect2, varscan2
- CFAP65 | c.4475G>A p.G1492E | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58565527; called by muse, mutect2, varscan2
- CFHR2 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV66381864; called by muse, mutect2, varscan2
- CFHR2 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV100804282, COSV66381888; called by muse, mutect2, varscan2
- CFHR3 | c.256A>T p.K86* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as rs554318034, COSV66403108; called by muse, mutect2, varscan2
- CHRM5 | c.829A>C p.S277R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.99); catalogued as COSV67248334; called by muse, mutect2, varscan2
- CIDEA | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1287496741, COSV100255008; called by muse, mutect2, varscan2
- CIDEA | c.641G>A p.G214D | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV100255009; called by muse, mutect2, varscan2
- CILP | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.091); catalogued as rs778436532, COSV56027240; called by muse, mutect2, varscan2
- CLTCL1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV54237643; called by muse, mutect2, varscan2
- CLU | c.370T>A p.F124I | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57068048; called by muse, mutect2, varscan2
- CNBD1 | c.1208G>A p.G403D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73074715, COSV73075938; called by muse, mutect2, varscan2
- CNGA2 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV61705886, COSV61706550; called by muse, mutect2, varscan2
- CNGA4 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.065); catalogued as COSV66006878; called by muse, mutect2, varscan2
- CNGB1 | c.3007C>T p.Q1003* | Nonsense Mutation (SNP) | VAF 57/146 reads (39%) | catalogued as COSV51905722; called by muse, mutect2, varscan2
- CNKSR1 | c.1637C>T p.P546L (on ENST00000374253 / NM_001297647.2; = p.P539L on NM_006314.3) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV58794328; called by muse, mutect2, varscan2
- CNOT10 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 160/421 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59394634; called by muse, mutect2, varscan2
- CNTN5 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs552066224, COSV54347878; called by muse, mutect2
- COL13A1 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62573961; called by muse, mutect2, varscan2
- COL13A1 | c.604G>A p.G202R (on ENST00000398978 / NM_001130103.2; = p.G164R on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62568849; called by muse, mutect2, varscan2
- COL22A1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV57329519; called by muse, mutect2, varscan2
- COL24A1 | c.1943G>A p.G648E | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65312382; called by muse, mutect2
- COL25A1 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as COSV67656871; called by muse, mutect2, varscan2
- COL28A1 | c.2819C>T p.P940L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV68084107; called by muse, mutect2, varscan2
- COL4A1 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65430693; called by muse, mutect2, varscan2
- COL4A5 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1052281498, COSV60366888; called by muse, mutect2, varscan2
- COL4A6 | c.2969G>A p.G990E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57874627; called by muse, mutect2, varscan2
- COL4A6 | c.2968G>T p.G990* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100563477, COSV100564831; called by muse, mutect2, varscan2
- COL5A1 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65673619; called by muse, mutect2, varscan2
- COL5A2 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs866611080, COSV66413986; called by muse, mutect2
- COL6A3 | c.3794G>A p.G1265D | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55104974; called by muse, mutect2, varscan2
- COL7A1 | c.5302G>A p.E1768K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs769961863, COSV60401814; called by muse, mutect2, varscan2
- COL7A1 | c.2528G>A p.R843Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.097); catalogued as rs747058637, COSV100095319, COSV60401094; called by muse, mutect2, varscan2
- COL9A1 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as COSV57891484; called by muse, mutect2, varscan2
- COPA | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 28/71 reads (39%) | catalogued as COSV54103529; called by muse, mutect2, varscan2
- COQ4 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV55957819; called by muse, mutect2, varscan2
- CPXM1 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as rs1448186605, COSV66044836; called by muse, mutect2, varscan2
- CR2 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV65508528; called by muse, mutect2, varscan2
- CRACR2A | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV52917391; called by muse, mutect2, varscan2
- CREBBP | c.1246A>G p.I416V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52137443; called by muse, mutect2, varscan2
- CREBRF | c.1804+1G>A p.X602_splice | Splice Site (SNP) | VAF 13/47 reads (28%) | catalogued as COSV51635724; called by muse, mutect2, varscan2
- CRLF2 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs759127718, COSV67493497; called by muse, mutect2, varscan2
- CSH2 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs561223596, COSV61080968; called by muse, mutect2, varscan2
- CSMD1 | c.10172G>A p.S3391N (on ENST00000520002; = p.S3390N on NM_033225.6) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59371123; called by muse, mutect2, varscan2
- CSMD1 | c.8962G>A p.G2988R (on ENST00000520002; = p.G2987R on NM_033225.6) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59344796; called by muse, mutect2, varscan2
- CSMD1 | c.1271C>T p.T424I (on ENST00000520002; = p.T423I on NM_033225.6) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV68207308; called by muse, mutect2, varscan2
- CSMD2 | c.8681G>A p.G2894E | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53952048; called by muse, mutect2, varscan2
- CSMD2 | c.5870G>A p.W1957* | Nonsense Mutation (SNP) | VAF 26/60 reads (43%) | catalogued as COSV53952065; called by muse, mutect2, varscan2
- CSMD2 | c.5563G>A p.G1855S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53952127; called by muse, mutect2, varscan2
- CSMD3 | c.5822G>A p.G1941E (on ENST00000297405 / NM_001363185.1; = p.G1837E on NM_052900.3) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52289908; called by muse, mutect2, varscan2
- CSMD3 | c.4707T>G p.I1569M (on ENST00000297405 / NM_001363185.1; = p.I1465M on NM_052900.3) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV52289932; called by muse, mutect2, varscan2
- CSMD3 | c.3643G>A p.E1215K (on ENST00000297405 / NM_001363185.1; = p.E1111K on NM_052900.3) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as COSV52289954; called by muse, mutect2, varscan2
- CSMD3 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1022309288, COSV52290002; called by muse, mutect2, varscan2
- CST5 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59015383; called by muse, mutect2, varscan2
- CTTNBP2 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV50458249; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 46/111 reads (41%) | catalogued as COSV54746514; called by muse, mutect2, varscan2
- CUX1 | c.1751G>A p.G584E | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52911993; called by muse, mutect2, varscan2
- CX3CR1 | c.689T>A p.I230N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV64195029; called by muse, mutect2, varscan2
- CXCL6 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56903355; called by muse, mutect2, varscan2
- CXorf56 | c.398G>A p.R133Q (on ENST00000536133 / NM_001170570.2; = p.R147Q on NM_022101.4) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as COSV57439096; called by muse, mutect2, varscan2
- CXorf58 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.112); catalogued as COSV101002951, COSV64858036; called by muse, mutect2, varscan2
- CYFIP1 | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.273); catalogued as rs139576657; called by muse, mutect2, varscan2
- CYFIP2 | c.2867A>T p.E956V (on ENST00000616178 / NM_001291722.2; = p.E931V on NM_014376.4) | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV59048779; called by muse, mutect2, varscan2
- CYP2C8 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV64878575; called by muse, mutect2, varscan2
- CYP4F3 | c.1398G>A p.R466= | Splice Region (SNP) | VAF 13/32 reads (41%) | catalogued as COSV55412089; called by muse, mutect2
- CYRIA | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62866740; called by muse, mutect2, varscan2
- CYTH4 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs868185751, COSV50634225; called by muse, mutect2
- DAG1 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.841); catalogued as COSV58183345; called by muse, mutect2, varscan2
- DAGLB | c.248-1G>A p.X83_splice | Splice Site (SNP) | VAF 21/41 reads (51%) | catalogued as COSV51706402; called by muse, mutect2, varscan2
- DAO | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57321442, COSV57324182; called by muse, mutect2, varscan2
- DCBLD2 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV58792578; called by muse, mutect2, varscan2
- DCC | c.3605G>A p.S1202N | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs150938467, COSV71431647; called by muse, mutect2, varscan2
- DCP2 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66618083; called by muse, mutect2, varscan2
- DDX20 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV63831018; called by muse, mutect2, varscan2
- DGKI | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55941877; called by muse, mutect2, varscan2
- DGKK | c.3049C>T p.Q1017* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV101052934; called by muse, mutect2, varscan2
- DIAPH1 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53887674; called by muse, mutect2, varscan2
- DIP2C | c.1739A>T p.K580M | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV55175223; called by muse, mutect2, varscan2
- DIRAS2 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs71494416, COSV65370678; called by muse, mutect2, varscan2
- DKK2 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs866892165, COSV53394617, COSV53399664; called by muse, mutect2, varscan2
- DLG2 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV54677661; called by muse, mutect2, varscan2
- DLGAP3 | c.2322G>A p.W774* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV52396751; called by muse, mutect2, varscan2
- DMBT1 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV57557852; called by muse, mutect2, varscan2
- DMBT1 | c.6415G>A p.G2139S (on ENST00000338354 / NM_001377530.1; = p.G1382S on NM_004406.3) | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as COSV57557871; called by muse, mutect2, varscan2
- DMD | c.5494G>A p.D1832N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV63784259; called by muse, mutect2, varscan2
- DNAH10 | c.2817G>A p.K939= (on ENST00000409039; = p.K878= on NM_207437.3) | Splice Region (SNP) | VAF 62/172 reads (36%) | catalogued as COSV68999805; called by muse, mutect2, varscan2
- DNAH11 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as COSV60975772; called by muse, mutect2
- DNAH17 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs560059384, COSV67760005; called by muse, mutect2, varscan2
- DNAH3 | c.11865G>A p.W3955* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV54503815; called by muse, mutect2, varscan2
- DNAH5 | c.9229C>T p.R3077W | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1426289211, COSV54225027, COSV54246679; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.071); catalogued as COSV100545366, COSV59473950; called by muse, mutect2, varscan2
- DNAH8 | c.791A>T p.N264I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59473974; called by muse, mutect2, varscan2
- DNAH8 | c.4816C>T p.P1606S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV59473996; called by muse, mutect2, varscan2
- DNM3 | c.1636G>A p.G546R (on ENST00000355305 / NM_001350206.2; = p.G536R on NM_015569.5) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV62464126; called by muse, mutect2, varscan2
- DOT1L | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV101288559; called by muse, mutect2, varscan2
- DPYD | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV64591675, COSV64594672; called by muse, mutect2, varscan2
- DPYD | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV60075134; called by muse, mutect2, varscan2
- DRP2 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV65811545; called by muse, mutect2, varscan2
- DSC2 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV51868318; called by muse, mutect2, varscan2
- DSC3 | c.2479C>T p.P827S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as COSV64574921; called by muse, mutect2, varscan2
- DSCAM | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV68034012; called by muse, mutect2, varscan2
- DSCAM | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as COSV68034016; called by muse, mutect2, varscan2
- DSG2 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs564135334, COSV55202102; called by muse, mutect2, varscan2
- DSP | c.4565C>G p.T1522R | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV65793138, COSV65793568; called by muse, mutect2, varscan2
- EDA | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.956); catalogued as COSV58875305, COSV58878617; called by muse, mutect2, varscan2
- EDN1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as COSV65081244; called by muse, mutect2, varscan2
- EFCAB6 | c.2798G>A p.G933D | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV53070563; called by muse, mutect2, varscan2
- EGF | c.2590G>A p.D864N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as COSV54483445; called by muse, mutect2, varscan2
- EIF2AK4 | c.1762A>C p.I588L | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV55473056; called by muse, mutect2, varscan2
- EIF4H | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs781809080, COSV56083164; called by muse, mutect2, varscan2
- ELMO2 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs781450905, COSV51685446; called by muse, mutect2, varscan2
- ELSPBP1 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV60414113; called by muse, mutect2, varscan2
- EMILIN2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs369108065; called by muse, mutect2, varscan2
- ENPEP | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54453540, COSV54456180; called by muse, mutect2, varscan2
- EPB41L5 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 61/89 reads (69%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.966); catalogued as COSV55352449; called by muse, mutect2, varscan2
- EPHA4 | c.2233C>T p.R745C | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56042113; called by muse, mutect2, varscan2
- EPHB3 | c.2256G>A p.M752I | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV57806953; called by muse, mutect2, varscan2
- EPHB6 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376846276, COSV67420093; called by muse, varscan2
- ERC2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55655515; called by muse, mutect2, varscan2
- ERICH3 | c.3694G>A p.G1232R | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV58604796, COSV58615738; called by muse, mutect2, varscan2
- ERICH3 | c.1045A>C p.S349R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58603273, COSV58615763; called by muse, mutect2, varscan2
- ERICH3 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV58615776; called by muse, mutect2, varscan2
- ESCO1 | c.1487T>C p.L496S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs766439316, COSV52522253; called by muse, mutect2, varscan2
- FAM114A1 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV62674494; called by muse, mutect2
- FAM120C | c.2146C>T p.R716W | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60261901; called by muse, mutect2, varscan2
- FAM47A | c.2328G>A p.M776I | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60495114, COSV60499311; called by muse, mutect2, varscan2
- FAM47C | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.376); catalogued as COSV100792471, COSV63729196; called by muse, mutect2, varscan2
- FAM47C | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.148); catalogued as COSV63729672; called by muse, mutect2, varscan2
- FAM47C | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV63726817; called by muse, mutect2, varscan2
- FAM71B | c.167A>G p.K56R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.453); catalogued as rs201454987, COSV57228004, COSV57230428; called by muse, mutect2, varscan2
- FAM81A | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55680254; called by muse, mutect2
- FANCM | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV57505425, COSV57507675; called by muse, mutect2, varscan2
- FAT3 | c.3463C>T p.P1155S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as COSV53162135; called by muse, mutect2, varscan2
- FBLN2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as COSV55489805; called by muse, mutect2, varscan2
- FBXL16 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV60965393; called by muse, mutect2, varscan2
- FBXL17 | c.1901G>A p.G634E | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62857609; called by muse, mutect2, varscan2
- FBXL17 | c.1900G>A p.G634R | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100670870; called by muse, mutect2, varscan2
- FBXO28 | c.865G>T p.V289L | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV64801306; called by muse, mutect2, varscan2
- FBXO40 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs768870158, COSV57526872; called by muse, mutect2, varscan2
- FBXO41 | c.1744G>A p.V582M | Missense Mutation (SNP) | VAF 48/66 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142820235; called by muse, mutect2, varscan2
- FCGR1A | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV64985980; called by muse, mutect2, varscan2
- FCRL4 | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs1290946597, COSV54865659; called by muse, mutect2, varscan2
- FGD5 | c.1333G>A p.G445R | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV53250036; called by muse, mutect2, varscan2
- FGF10 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV52938702; called by muse, mutect2, varscan2
- FGF5 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 41/108 reads (38%) | catalogued as COSV56891621; called by muse, mutect2, varscan2
- FGF9 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66645492; called by muse, mutect2, varscan2
- FGR | c.228G>A p.G76= | Splice Region (SNP) | VAF 4/18 reads (22%) | catalogued as COSV64969497, COSV64969729; called by muse, mutect2
- FILIP1L | c.1996G>A p.E666K (on ENST00000354552 / NM_182909.3; = p.E426K on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV58771335; called by muse, mutect2, varscan2
- FKBP6 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as COSV52722500; called by muse, mutect2, varscan2
- FLRT3 | c.1908C>A p.Y636* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as COSV54039756; called by muse, mutect2, varscan2
- FMN2 | c.3109C>T p.P1037S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs148115484, COSV60433101; called by muse, varscan2
- FMO1 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138644882, COSV61447447; called by muse, mutect2, varscan2
- FOXR1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV57653553; called by muse, mutect2, varscan2
- FRMPD4 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66221657; called by muse, mutect2, varscan2
- FRMPD4 | c.2650G>A p.E884K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV66210876, COSV66221662; called by muse, mutect2, varscan2
- FRMPD4 | c.3316G>A p.G1106R | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1430480740, COSV66221665; called by muse, mutect2, varscan2
- FRY | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969038, COSV66577517; called by muse, mutect2, varscan2
- FRY | c.4975G>A p.D1659N | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV66577523; called by muse, mutect2, varscan2
- FSTL5 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV60200872, COSV60222471; called by muse, mutect2, varscan2
- FUT3 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.878); catalogued as COSV54607844; called by muse, mutect2, varscan2
- FYB2 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV58588353; called by muse, mutect2
- GABPA | c.1294C>T p.H432Y | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.221); catalogued as COSV61395761, COSV61397371; called by muse, mutect2, varscan2
- GABRA3 | c.1253A>C p.K418T | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.525); catalogued as rs754211358, COSV64804000; called by muse, mutect2, varscan2
- GATA1 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV64962775, COSV64963270; called by muse, mutect2, varscan2
- GATA5 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs782700910, COSV53347173; called by muse, mutect2
- GDF15 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV53251620; called by muse, mutect2, varscan2
- GFPT2 | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV53811608; called by muse, mutect2, varscan2
- GHR | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50106373; called by muse, mutect2, varscan2
- GHSR | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as COSV53841123; called by muse, mutect2, varscan2
- GID8 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV56612197; called by muse, mutect2, varscan2
- GIMAP6 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV61032855; called by muse, mutect2, varscan2
- GIPR | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV54425955; called by muse, mutect2, varscan2
- GLDN | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV59091992; called by muse, mutect2, varscan2
- GLIS3 | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100174181, COSV60934182; called by muse, mutect2, varscan2
- GLYATL1 | c.756G>A p.M252I (on ENST00000317391 / NM_001354699.1; = p.M283I on NM_080661.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55610872; called by muse, mutect2, varscan2
- GORAB | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.178); catalogued as rs1483223031, COSV63028746; called by muse, mutect2, varscan2
- GPC4 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV63699456; called by muse, mutect2, varscan2
- GPC5 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.53); catalogued as COSV65599440, COSV65633589; called by muse, mutect2, varscan2
- GPC6 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65500845; called by muse, mutect2, varscan2
- GPRASP2 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV59992263; called by muse, mutect2, varscan2
- GPRC6A | c.1181G>A p.R394K | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV59951340; called by muse, mutect2, varscan2
- GRIN2A | c.4324C>T p.P1442S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV58029477, COSV58053167; called by muse, mutect2, varscan2
- GRIN2A | c.1787G>A p.G596E | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58053184; called by muse, mutect2, varscan2
- GRIN2A | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs199942034, COSV58035084, COSV58053195; called by muse, mutect2, varscan2
- GRK4 | c.941A>G p.K314R (on ENST00000398052 / NM_182982.3; = p.K282R on NM_005307.3) | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61670723; called by muse, mutect2, varscan2
- GRN | c.205G>C p.A69P | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV50008624; called by muse, mutect2
- GSDME | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs145754170; ClinVar: uncertain significance; called by muse, mutect2
- GTF2IRD2 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100736396; called by muse, mutect2, varscan2
- HADHB | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV58548272; called by muse, mutect2, varscan2
- HAPLN2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1231256003, COSV54816464; called by muse, mutect2, varscan2
- HCN1 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV57532725; called by muse, mutect2, varscan2
- HEPH | c.386G>A p.G129D (on ENST00000343002; = p.G183D on NM_138737.5) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57970403; called by muse, mutect2, varscan2
- HIRA | c.2995C>T p.R999* | Nonsense Mutation (SNP) | VAF 24/56 reads (43%) | catalogued as COSV54278526; called by muse, mutect2, varscan2
- HIVEP1 | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65104384; called by muse, mutect2, varscan2
- HIVEP2 | c.1625G>A p.R542K | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50044150; called by muse, mutect2, varscan2
- HJURP | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs1463238389, COSV64979425; called by muse, mutect2, varscan2
- HLA-DMA | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66386020; called by muse, mutect2, varscan2
- HLA-DMA | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs1050991184, COSV66386057; called by muse, mutect2, varscan2
- HLA-G | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1052565663, COSV64406642; called by muse, mutect2, varscan2
- HSD11B1 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54829284; called by muse, mutect2, varscan2
- HSD3B7 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52681827; called by muse, mutect2, varscan2
- HSPA4 | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59181801; called by muse, mutect2, varscan2
- HYDIN | c.11705G>A p.G3902E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV66641699; called by muse, mutect2, varscan2
- IFNG | c.176G>A p.W59* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV57491947; called by muse, mutect2, varscan2
- IFT80 | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV58451272; called by muse, mutect2, varscan2
- IGHD | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); catalogued as rs1161946198, COSV101162820; called by muse, mutect2, varscan2
- IGHV3-43 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs751115881; called by muse, mutect2, varscan2
- IGHV3-53 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.286); catalogued as rs782414781; called by muse, mutect2, varscan2
- IGHV3-66 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.141); catalogued as rs782513119; called by muse, mutect2, varscan2
- IGHV5-51 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs782043169; called by muse, mutect2, varscan2
- IGHV5-51 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.638); catalogued as rs1567621894; called by muse, mutect2, varscan2
- IGKV1D-8 | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs776382493; called by muse, mutect2, varscan2
- IGSF10 | c.3244C>T p.P1082S | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV56785718; called by muse, mutect2, varscan2
- IL17B | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51004571; called by muse, mutect2, varscan2
- IL17RD | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs145766256; called by muse, varscan2
- IL17RE | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs138199794; called by muse, mutect2
- IL21R | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); catalogued as rs1401969058, COSV61973005; called by muse, mutect2, varscan2
- IL5RA | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV56524800; called by muse, mutect2, varscan2
- INCENP | c.2681C>T p.S894F (on ENST00000394818 / NM_001040694.2; = p.S890F on NM_020238.3) | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53920106; called by muse, mutect2, varscan2
- IPO11 | c.1807G>A p.V603I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100320435; called by muse, mutect2, varscan2
- IQCN | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV66577033; called by muse, mutect2, varscan2
- IQGAP2 | c.1072-1G>A p.X358_splice | Splice Site (SNP) | VAF 17/40 reads (43%) | catalogued as COSV57180158; called by muse, mutect2, varscan2
- IRAG1 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.854); catalogued as COSV70212727; called by muse, mutect2, varscan2
- IRX1 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs370996288, COSV57361906; called by muse, mutect2, varscan2
- ITGA4 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52001850, COSV52003303; called by muse, mutect2, varscan2
- ITGA8 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.409); catalogued as COSV65229176; called by muse, mutect2, varscan2
- ITGAE | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 104/148 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1427566077, COSV53998556; called by muse, mutect2, varscan2
- ITGB1BP2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52139905; called by muse, mutect2, varscan2
- ITPKB | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs984533443, COSV55267919; called by muse, mutect2, varscan2
- ITPR3 | c.4022C>T p.S1341L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755528499, COSV65413914; called by muse, mutect2, varscan2
- ITPRID1 | c.1364C>A p.P455Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV60081227; called by muse, mutect2, varscan2
- JADE2 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV50927855; called by muse, mutect2, varscan2
- JAM2 | c.504G>A p.W168* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as rs1230941179, COSV57260157; called by muse, mutect2, varscan2
- KALRN | c.8032G>A p.E2678K (on ENST00000360013 / NM_001024660.4; = p.E981K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV52261951; called by muse, mutect2, varscan2
- KANSL1 | c.3029G>A p.R1010Q (on ENST00000574590 / NM_001193465.2; = p.R1011Q on NM_015443.4) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV52246256; called by muse, mutect2, varscan2
- KCNB2 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV73049934; called by muse, mutect2, varscan2
- KCNJ4 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.42); catalogued as COSV57858463; called by muse, mutect2, varscan2
- KCNJ9 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1177979618, COSV63632393; called by muse, mutect2
- KCNQ5 | c.2401G>A p.D801N | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV100572563, COSV59678151; called by muse, mutect2, varscan2
- KCNS3 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.3); catalogued as COSV58408595; called by muse, mutect2, varscan2
- KCNT2 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV54068840; called by muse, mutect2, varscan2
- KIAA1109 | c.4594C>T p.R1532C | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52688572; called by muse, mutect2, varscan2
- KIAA1210 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.621); catalogued as COSV68179535; called by muse, mutect2, varscan2
- KIAA1217 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as rs1214630546, COSV100287045, COSV56813039; called by muse, mutect2, varscan2
- KIF2B | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52130550; called by muse, mutect2, varscan2
- KIF3A | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762622525, COSV66413366; called by muse, mutect2, varscan2
- KLHL13 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as rs758950986, COSV53245230; called by muse, mutect2, varscan2
- KLHL25 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61996207; called by muse, mutect2, varscan2
- KLHL35 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.209); catalogued as rs764407435, COSV66219663; called by muse, mutect2, varscan2
- KLKB1 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52998560; called by muse, mutect2, varscan2
- KMT2A | c.2509C>T p.P837S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.158); catalogued as COSV63291229; called by muse, mutect2, varscan2
- KRT23 | c.818A>T p.E273V | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV52928813; called by muse, mutect2, varscan2
- KRT32 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99862956; called by muse, mutect2, varscan2
- KRT32 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs764491682, COSV56787823; called by muse, mutect2, varscan2
- KRT76 | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1176950636, COSV60119809; called by muse, mutect2, varscan2
- KRTAP10-12 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 60/91 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs1020228702, COSV59975472; called by muse, mutect2, varscan2
- KRTAP5-1 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); catalogued as COSV66299236; called by muse, mutect2, varscan2
- KSR2 | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56670955; called by muse, mutect2, varscan2
- L3MBTL1 | c.1793C>T p.S598F (on ENST00000418998 / NM_001377303.1; = p.S508F on NM_015478.7) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64229489; called by muse, mutect2, varscan2
- L3MBTL4 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs973379316, COSV53137395; called by muse, mutect2, varscan2
- LACRT | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/40 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57687688; called by muse, mutect2, varscan2
- LAMA3 | c.6731C>T p.A2244V (on ENST00000313654 / NM_198129.4; = p.A635V on NM_000227.6) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV52541528; called by muse, mutect2, varscan2
- LCK | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1318678254, COSV60742275; called by muse, mutect2, varscan2
- LHX6 | c.564G>A p.M188I (on ENST00000373755 / NM_001242334.2; = p.M217I on NM_014368.5) | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV61345893; called by muse, mutect2, varscan2
- LILRA4 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.966); catalogued as COSV52494227; called by muse, mutect2, varscan2
- LILRB1 | c.1391C>T p.S464F (on ENST00000427581; = p.S428F on NM_006669.6) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs1300963253, COSV61121120; called by muse, mutect2
- LILRB2 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.072); catalogued as COSV58747846; called by muse, mutect2, varscan2
- LIMCH1 | c.2582G>A p.G861E | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58294044; called by muse, mutect2
- LIPF | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV53285992; called by muse, mutect2, varscan2
- LONRF1 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV68037645; called by muse, mutect2, varscan2
- LRP1B | c.11620C>T p.Q3874* | Nonsense Mutation (SNP) | VAF 20/30 reads (67%) | catalogued as COSV67213919; called by muse, mutect2, varscan2
- LRRC14 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV52881930; called by muse, mutect2, varscan2
- LRRC4C | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53424272; called by muse, mutect2, varscan2
- LRRC7 | c.1814G>A p.R605Q (on ENST00000651989 / NM_001370785.2; = p.R572Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs763720419, COSV50410760, COSV99065864; called by muse, mutect2, varscan2
- LRRFIP1 | c.1319C>T p.S440L (on ENST00000392000 / NM_001137552.2; = p.S416L on NM_004735.4) | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as COSV55255767; called by muse, mutect2, varscan2
- LRRIQ1 | c.2504G>A p.S835N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV67837016; called by muse, mutect2, varscan2
- LRRIQ1 | c.3415C>T p.L1139F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV67837026; called by muse, mutect2, varscan2
- LY75 | c.1146G>A p.W382* | Nonsense Mutation (SNP) | VAF 27/43 reads (63%) | catalogued as rs1307807321, COSV99716194; called by muse, mutect2, varscan2
- LY75 | c.1145G>A p.W382* | Nonsense Mutation (SNP) | VAF 29/46 reads (63%) | catalogued as COSV99716195; called by muse, mutect2, varscan2
- LYSMD2 | c.602G>A p.S201N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV51057096; called by muse, mutect2, varscan2
- MAGEA12 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV63295300; called by muse, mutect2
- MAGEB2 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763345977, COSV66781576; called by muse, mutect2, varscan2
- MAGEB3 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1243412141, COSV64397630; called by muse, mutect2, varscan2
- MAGEB6B | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as rs771424539; called by muse, mutect2, varscan2
- MAP1B | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs756153336, COSV57098133; called by muse, mutect2, varscan2
- MAP3K14 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.56); PolyPhen benign (0.025); catalogued as COSV59304764; called by muse, mutect2, varscan2
- MAP3K14 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV60924837; called by muse, mutect2, varscan2
- MAP3K15 | c.1716G>A p.W572* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV58828731; called by muse, mutect2, varscan2
- MAP3K21 | c.2357A>T p.E786V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV64042383; called by muse, varscan2
- MAPK8IP1 | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as rs965375257, COSV53799546; called by muse, mutect2, varscan2
- MARCHF10 | c.1749G>A p.M583I | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV60887519; called by muse, mutect2, varscan2
- MARK3 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372041993; called by muse, mutect2, varscan2
- MASP2 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs748760302, COSV68897366; ClinVar: uncertain significance; called by muse, mutect2
- MATN4 | c.1474C>T p.R492C (on ENST00000372754; = p.R451C on NM_003833.4) | Missense Mutation (SNP) | VAF 42/81 reads (52%) | PolyPhen probably damaging (0.987); catalogued as rs778298691, COSV61350538; called by muse, mutect2, varscan2
- MCM4 | c.1627C>T p.L543F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50627252; called by muse, mutect2, varscan2
- MCM7 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531476711, COSV57998500; called by muse, mutect2, varscan2
- MDM1 | c.1666A>T p.K556* | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as COSV57448430; called by muse, mutect2, varscan2
- MEGF10 | c.3334G>A p.D1112N | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57249082; called by muse, mutect2, varscan2
- MEPCE | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52769842; called by muse, mutect2, varscan2
- MEPE | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.317); catalogued as COSV63074171; called by muse, mutect2, varscan2
- MFNG | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs1465636512, COSV63690766; called by muse, mutect2, varscan2
- MGAM | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs782236312, COSV71885941; called by muse, mutect2, varscan2
- MGAM | c.2446C>T p.R816* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as rs368880817; called by muse, varscan2
- MGAM | c.5050G>A p.D1684N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.724); catalogued as COSV72075431; called by muse, mutect2, varscan2
- MGLL | c.427G>A p.V143I (on ENST00000398104 / NM_001003794.2; = p.V153I on NM_007283.6) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV54029167; called by muse, mutect2, varscan2
- MIB1 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as rs1317522131, COSV55087426; called by muse, mutect2, varscan2
- MICAL2 | c.4306G>A p.E1436K | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1222130181, COSV56288171; called by muse, mutect2, varscan2
- MIIP | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52427327; called by muse, mutect2, varscan2
- MLXIPL | c.1856C>T p.S619F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV57669773; called by muse, mutect2, varscan2
- MMP2 | c.1623G>A p.W541* | Nonsense Mutation (SNP) | VAF 28/53 reads (53%) | catalogued as COSV54604582; called by muse, mutect2, varscan2
- MORC1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV51713955; called by muse, mutect2, varscan2
- MPP1 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs781808389, COSV65728010, COSV65728208; called by muse, mutect2, varscan2
- MPP6 | c.736G>T p.G246* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV56040104, COSV56041744; called by muse, mutect2, varscan2
- MROH2B | c.4136G>A p.R1379Q | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as rs753433063, COSV68182217; called by muse, mutect2, varscan2
- MRPL2 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV52438656; called by muse, mutect2, varscan2
- MSX1 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66947767; called by muse, mutect2, varscan2
- MTM1 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as rs886044782, CP973606, COSV100080294; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- MTMR10 | c.1520C>A p.S507Y | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV58728045, COSV58729590; called by muse, mutect2, varscan2
- MTUS2 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV70920562; called by muse, mutect2, varscan2
- MTUS2 | c.1829C>T p.S610F | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs779627131, COSV70916843; called by muse, mutect2, varscan2
- MTUS2 | c.2049G>T p.K683N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV70920564; called by muse, mutect2, varscan2
- MUC15 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55554181; called by muse, mutect2, varscan2
- MUC16 | c.28076G>A p.R9359K | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.031); catalogued as COSV67487567; called by muse, mutect2, varscan2
- MUC16 | c.23899A>G p.K7967E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67487572; called by muse, mutect2, varscan2
- MUC16 | c.16738C>T p.L5580F | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1393938181, COSV67483493, COSV67487582; called by muse, mutect2, varscan2
- MUC16 | c.16256C>T p.S5419F | Missense Mutation (SNP) | VAF 123/352 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.279); catalogued as rs199879843, COSV101199999; called by muse, mutect2, varscan2
- MUC16 | c.11140C>T p.H3714Y | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs867039375, COSV67487590; called by muse, mutect2, varscan2
- MUC16 | c.5123C>T p.T1708I | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV67487602; called by muse, mutect2, varscan2
- MUC21 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV66221960; called by muse, mutect2, varscan2
- MUCL1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58193648; called by muse, mutect2, varscan2
- MYH4 | c.5235G>A p.M1745I | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV55116150; called by muse, mutect2, varscan2
- MYH8 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV67959790; called by muse, mutect2, varscan2
- MYO5B | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53228462; called by muse, mutect2, varscan2
- MYOC | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV50677659; called by muse, mutect2, varscan2
- MYOCD | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 55/79 reads (70%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs751148214, COSV58497739; called by muse, mutect2, varscan2
- MYOCD | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV58506770; called by muse, mutect2, varscan2
- NAA10 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64170482; called by muse, mutect2, varscan2
- NAA25 | c.1612C>A p.Q538K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55708026; called by muse, mutect2, varscan2
- NAALADL1 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60525562; called by muse, mutect2, varscan2
- NAV1 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.111); catalogued as COSV55224323; called by muse, mutect2, varscan2
- NAV3 | c.6861A>T p.E2287D (on ENST00000397909 / NM_001024383.2; = p.E2265D on NM_014903.6) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57106181; called by muse, mutect2, varscan2
- NBEA | c.4234G>A p.G1412S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs950706799, COSV59815227; called by muse, mutect2, varscan2
- NCAM1 | c.1778G>A p.G593E (on ENST00000316851 / NM_181351.5; = p.G583E on NM_000615.7) | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100378249; called by muse, mutect2
- NCAN | c.3652C>T p.P1218S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53056980; called by muse, mutect2, varscan2
- NCOR2 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62302907; called by muse, mutect2, varscan2
- NCR2 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.307); catalogued as rs1254863108, COSV66101189; called by muse, mutect2, varscan2
- NECTIN2 | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.308); catalogued as COSV52979580; called by muse, mutect2, varscan2
- NECTIN4 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as COSV63513802; called by muse, mutect2, varscan2
- NEK5 | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.062); catalogued as rs200511571, COSV62881558; called by muse, mutect2, varscan2
- NELL2 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV61568521; called by muse, mutect2, varscan2
- NEXMIF | c.2651A>G p.N884S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV50081940; called by muse, mutect2, varscan2
- NFRKB | c.2702C>T p.A901V (on ENST00000446488 / NM_001143835.2; = p.A926V on NM_006165.3) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.366); catalogued as rs756253394, COSV58760057; called by muse, mutect2, varscan2
- NGLY1 | c.774G>T p.R258S | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV54990098; called by muse, mutect2, varscan2
- NID1 | c.3228G>A p.G1076= | Splice Region (SNP) | VAF 4/16 reads (25%) | catalogued as rs1284637976, COSV99937214; called by muse, mutect2
- NID1 | c.3228-1G>A p.X1076_splice | Splice Site (SNP) | VAF 4/15 reads (27%) | catalogued as COSV51624780; called by muse, mutect2
- NID2 | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53501590; called by muse, mutect2, varscan2
- NLGN4X | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.05); catalogued as COSV52032997, COSV99323631; called by muse, mutect2, varscan2
- NLGN4X | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057524668, COSV52033040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP13 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); catalogued as rs753708026, COSV61621590; called by muse, mutect2, varscan2
- NLRP9 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs759340206, COSV60461331; called by muse, mutect2, varscan2
- NMT1 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.402); catalogued as COSV51962226; called by muse, mutect2, varscan2
- NOL4 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 33/108 reads (31%) | catalogued as COSV52358942; called by muse, mutect2, varscan2
- NOS1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.285); catalogued as rs1461864723, COSV57619813; called by muse, mutect2
- NOTCH4 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV66682296; called by muse, mutect2, varscan2
- NOX4 | c.57G>A p.L19= | Splice Region (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99630042; called by muse, varscan2
- NPAP1 | c.3215G>A p.G1072E | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.065); catalogued as rs755028786, COSV100275979, COSV61508902; called by muse, mutect2, varscan2
- NPBWR2 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs769015617, COSV63900320; called by muse, mutect2, varscan2
- NPR2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as COSV61314146; called by muse, mutect2, varscan2
- NPSR1 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.023); catalogued as COSV62206397; called by muse, mutect2, varscan2
- NPTXR | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV60729353; called by muse, mutect2
- NPTXR | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60729358; called by muse, mutect2, varscan2
- NRAP | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.73); PolyPhen benign (0.41); catalogued as rs965751106, COSV63493355; called by muse, mutect2
- NRDC | c.1945C>T p.L649F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61407767; called by muse, mutect2, varscan2
- NSRP1 | c.574G>C p.V192L | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV55935106; called by muse, mutect2, varscan2
- NT5DC2 | c.438-1G>A p.X146_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | catalogued as COSV58741747; called by muse, mutect2, varscan2
- NUP58 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as rs1188863869, COSV67751980; called by muse, mutect2, varscan2
- NWD1 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.417); catalogued as COSV60349763, COSV60353955; called by muse, mutect2, varscan2
- OBSCN | c.11242G>A p.G3748R | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52817178; called by muse, mutect2, varscan2
- OGDHL | c.2714A>T p.Q905L | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV65104188; called by muse, mutect2, varscan2
- ONECUT2 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV72203709; called by muse, mutect2, varscan2
- OR10C1 | c.589G>A p.E197K (on ENST00000622521; = p.E195K on NM_013941.3) | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as COSV65822947; called by muse, mutect2, varscan2
- OR10K1 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV56870715; called by muse, mutect2, varscan2
- OR10S1 | c.542T>A p.L181H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV73343004; called by muse, mutect2, varscan2
- OR10T2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1487870905, COSV100554785, COSV57783034; called by muse, varscan2
- OR13C4 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs548070868, COSV52928122; called by muse, mutect2, varscan2
- OR13C5 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV66165241; called by muse, mutect2, varscan2
- OR2A12 | c.422C>T p.T141I | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV68821881; called by muse, mutect2, varscan2
- OR2A25 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs781251490, COSV68716866, COSV68716922; called by muse, mutect2, varscan2
- OR2B6 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55128977; called by muse, mutect2, varscan2
- OR2T12 | c.776G>A p.R259K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as COSV58779151; called by muse, mutect2, varscan2
- OR2W1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs896592244, COSV65851468; called by muse, mutect2, varscan2
- OR4C15 | c.969G>A p.M323I (on ENST00000314644; = p.M269I on NM_001001920.2) | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.017); catalogued as COSV58954007; called by muse, mutect2, varscan2
- OR4F21 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as COSV100307490; called by mutect2, varscan2
- OR4M1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs760327097, COSV60059765, COSV60060322, COSV60060528; called by muse, varscan2
- OR4M1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60063023, COSV60063140; called by muse, mutect2, varscan2
- OR4N2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV60050752, COSV60054304; called by muse, varscan2
- OR51A4 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); catalogued as COSV66749959; called by muse, mutect2, varscan2
- OR52E2 | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV58612171; called by muse, mutect2, varscan2
- OR52L1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59987712; called by muse, varscan2
- OR52L1 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs1161346731, COSV59988786; called by muse, varscan2
- OR56A3 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61569689; called by muse, varscan2
- OR56A3 | c.871C>T p.L291F | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV61569844; called by muse, varscan2
- OR5B17 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as rs199698092, COSV62159833; called by muse, mutect2, varscan2
- OR5D18 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as COSV61738360; called by muse, mutect2, varscan2
- OR6C6 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV64456138; called by muse, mutect2, varscan2
- OR6C65 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV65569242; called by muse, mutect2, varscan2
- OR6S1 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV57839069; called by muse, mutect2, varscan2
- OR8G1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.056); catalogued as rs368405472; called by muse, mutect2, varscan2
- OR8G5 | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.36); catalogued as COSV100422311; called by muse, mutect2, varscan2
- OR9A4 | c.155A>T p.K52I | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as COSV71885939; called by muse, mutect2, varscan2
- OSMR | c.249G>A p.G83= | Splice Region (SNP) | VAF 12/39 reads (31%) | catalogued as rs1206371897, COSV57090560; called by muse, varscan2
- OSMR | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.284); catalogued as COSV57090569; called by muse, varscan2
- OSMR | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV57090579; called by muse, varscan2
- OTUD3 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs369009180; called by muse, mutect2, varscan2
- OXA1L | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.025); catalogued as rs866495733, COSV53537277; called by muse, mutect2, varscan2
- PAGE5 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV56944303; called by muse, mutect2, varscan2
- PAM | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57218498; called by muse, mutect2, varscan2
- PAPPA | c.2783G>A p.G928E | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as rs867691997, COSV60290284; called by muse, mutect2, varscan2
- PAPPA2 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV62776052; called by muse, mutect2, varscan2
- PASK | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52158953; called by muse, mutect2, varscan2
- PCCB | c.1339C>T p.L447F | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52447747; called by muse, mutect2, varscan2
- PCDH11X | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV53461991; called by muse, mutect2, varscan2
- PCDH11X | c.2042C>T p.S681F | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV53496926; called by muse, mutect2, varscan2
- PCDH15 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57312761, COSV57377455; called by muse, mutect2, varscan2
- PCDH15 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs192813057, COSV57279849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH8 | c.2237G>A p.W746* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as COSV58814701; called by muse, mutect2
- PCDH9 | c.2639C>T p.S880F | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.763); catalogued as rs755195441, COSV60582216; called by muse, mutect2, varscan2
- PCDHA10 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.314); catalogued as COSV100247731, COSV56486136; called by muse, mutect2, varscan2
- PCDHA13 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV56486128, COSV56538048; called by muse, varscan2
- PCDHA13 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.276); catalogued as COSV56538059; called by muse, varscan2
- PCDHA8 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65338774; called by muse, mutect2, varscan2
- PCDHA8 | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs376777545, COSV100969187; called by muse, mutect2, varscan2
- PCDHB12 | c.791T>G p.V264G | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV53400163; called by muse, mutect2, varscan2
- PCDHB12 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV53393221; called by muse, mutect2, varscan2
- PCDHB3 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.029); catalogued as rs782010092, COSV50617472; called by muse, mutect2, varscan2
- PCDHB4 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.967); catalogued as COSV52022782; called by muse, mutect2, varscan2
- PCDHB7 | c.1892G>A p.S631N | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV50806038; called by muse, mutect2, varscan2
- PCDHB8 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.558); catalogued as COSV99176441; called by muse, varscan2
- PCDHB9 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.77); catalogued as COSV53382792; called by muse, mutect2, varscan2
- PCDHB9 | c.1480C>A p.Q494K | Missense Mutation (SNP) | VAF 90/269 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.209); catalogued as COSV53382797; called by muse, mutect2, varscan2
- PCDHGA1 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV65298806; called by muse, mutect2, varscan2
- PCDHGA3 | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 45/135 reads (33%) | catalogued as rs753949657, COSV54013588; called by muse, mutect2, varscan2
- PCDHGA3 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as COSV53962621; called by muse, mutect2, varscan2
- PCDHGA5 | c.250T>G p.L84V | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV54013664; called by muse, mutect2, varscan2
- PCDHGA7 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs746106528, COSV53948934, COSV54013687; called by muse, mutect2, varscan2
- PCED1B | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.066); catalogued as rs868095731, COSV71395414; called by muse, mutect2, varscan2
- PDE4DIP | c.4784C>T p.S1595F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs587716674, COSV57723090; called by muse, mutect2
- PDE4DIP | c.5677G>A p.G1893S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV57723065; called by muse, mutect2, varscan2
- PDLIM4 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1459127799, COSV53804461; called by muse, mutect2, varscan2
- PDPR | c.2486T>G p.V829G | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV55355679; called by muse, mutect2, varscan2
- PDX1 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1384588250, COSV66847419; called by muse, mutect2, varscan2
- PDXDC1 | c.387C>T p.F129= | Splice Region (SNP) | VAF 21/111 reads (19%) | catalogued as rs756803032, COSV57911040; called by muse, mutect2, varscan2
- PDZD4 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.867); catalogued as rs782307434, COSV51250133; called by muse, mutect2, varscan2
- PEG3 | c.4195G>A p.V1399M | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as rs762643937, COSV55644376; called by muse, mutect2, varscan2
- PEG3 | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55629994; called by muse, mutect2, varscan2
- PHC1 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs771342943, COSV70418610; called by muse, mutect2, varscan2
- PHLDB3 | c.1912C>T p.H638Y | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs922147803, COSV99415311; called by muse, mutect2, varscan2
- PIK3C2G | c.2719G>A p.E907K (on ENST00000676171; = p.E866K on NM_004570.5) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV56828360; called by muse, mutect2, varscan2
- PIP5K1A | c.1592C>T p.P531L (on ENST00000368888 / NM_001135638.2; = p.P518L on NM_003557.3) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1465434285, COSV100576559; called by muse, mutect2, varscan2
- PITPNA | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV57936050; called by muse, mutect2, varscan2
- PJA1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.72); catalogued as rs1303491714, COSV64053665; called by muse, mutect2, varscan2
- PJA2 | c.2069C>T p.S690F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV63272070; called by muse, mutect2, varscan2
- PKD1 | c.2882C>A p.S961* | Nonsense Mutation (SNP) | VAF 38/122 reads (31%) | catalogued as COSV51923949; called by muse, mutect2
- PKHD1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61866644; called by muse, mutect2, varscan2
- PKLR | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61362367; called by muse, mutect2, varscan2
- PLA2G4A | c.1767A>G p.E589= | Splice Region (SNP) | VAF 9/30 reads (30%) | catalogued as COSV66556287; called by muse, mutect2, varscan2
- PLCB1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV62038366; called by muse, mutect2, varscan2
- PLCB4 | c.2072C>T p.S691F | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53797349, COSV53799526; called by muse, mutect2, varscan2
- PLCD3 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as rs962575710, COSV59562629; called by muse, mutect2, varscan2
- PLCH1 | c.3373G>A p.G1125R (on ENST00000340059 / NM_001130960.2; = p.G1117R on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV58187431, COSV58208271; called by muse, mutect2, varscan2
- PLCZ1 | c.1672G>A p.G558S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs761628985, COSV56849208; called by muse, mutect2, varscan2
- PLEKHA7 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs992892348, COSV63050042; called by muse, mutect2, varscan2
- PLEKHG2 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV52688715; called by muse, mutect2, varscan2
- PLEKHG2 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs1291944035, COSV52688742; called by muse, mutect2, varscan2
- PLEKHG3 | c.2933C>T p.S978F (on ENST00000394691; = p.S1034F on NM_001308147.2) | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as COSV55977682; called by muse, mutect2, varscan2
- PLXNA3 | c.4408C>T p.R1470C | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63753491; called by muse, mutect2, varscan2
- PLXNC1 | c.4513A>C p.T1505P | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as COSV51581802; called by muse, mutect2, varscan2
- PNMA3 | c.23A>T p.D8V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100937576, COSV64723053; called by muse, mutect2, varscan2
- POLG2 | c.995T>C p.V332A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.503); catalogued as COSV73376988; called by muse, mutect2, varscan2
- POLR3A | c.3502C>T p.H1168Y | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV64931890; called by muse, mutect2, varscan2
- POM121C | c.2885C>G p.P962R (on ENST00000607367; = p.P720R on NM_001099415.3) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57548635; called by muse, mutect2, varscan2
- POM121L12 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs766537069, COSV68692604; called by muse, mutect2, varscan2
- POU1F1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV60157313; called by muse, mutect2, varscan2
- PPDPFL | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57462077; called by muse, mutect2, varscan2
- PPFIA1 | c.2672T>C p.V891A | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV54139731; called by muse, mutect2, varscan2
- PPFIA2 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61049865; called by muse, mutect2, varscan2
- PPFIBP2 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55081418; called by muse, mutect2, varscan2
- PPP1R12B | c.752G>A p.W251* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as rs1393116260, COSV61122572; called by muse, mutect2, varscan2
- PPP2R1A | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1177432332, COSV59047668; called by muse, mutect2, varscan2
- PPP2R5E | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.477); catalogued as COSV61741436, COSV61743885; called by muse, mutect2, varscan2
- PPP3CA | c.1371T>A p.A457= | Splice Region (SNP) | VAF 9/29 reads (31%) | catalogued as COSV59929757; called by muse, mutect2, varscan2
- PPP4R3A | c.2206C>T p.L736F (on ENST00000554943 / NM_001366432.1; = p.L723F on NM_001284280.1) | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV61504252, COSV61505957; called by muse, mutect2, varscan2
- PPP6R1 | c.2640C>T p.S880= | Splice Region (SNP) | VAF 8/24 reads (33%) | catalogued as COSV58985103; called by muse, mutect2, varscan2
- PPRC1 | c.524C>A p.P175Q | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV53387875; called by muse, varscan2
- PRAF2 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as COSV59876843; called by muse, mutect2, varscan2
- PRAMEF14 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58049433; called by muse, mutect2, varscan2
- PRAMEF20 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 128/341 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1018071711, COSV57080962; called by muse, mutect2, varscan2
- PRB3 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 165/377 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs1283803436, COSV54392792; called by muse, varscan2
- PRDM11 | c.1411C>T p.P471S (on ENST00000530656 / NM_001359633.1; = p.P437S on NM_001256695.1) | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.172); catalogued as COSV55443011; called by muse, mutect2, varscan2
- PRDM16 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.257); catalogued as COSV54605145; called by muse, mutect2, varscan2
- PRDM9 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.291); catalogued as COSV57011833; called by muse, mutect2, varscan2
- PRKAA2 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV64805964, COSV64806075; called by muse, mutect2, varscan2
- PRKCQ | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as COSV54117499; called by muse, mutect2, varscan2
- PRR19 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs749677273, COSV100003707; called by muse, mutect2, varscan2
- PRRC2C | c.6679C>T p.P2227S (on ENST00000367742; = p.P2225S on NM_015172.4) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.311); catalogued as rs749749081, COSV58904760; called by muse, mutect2, varscan2
- PSPC1 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as rs370436337; called by muse, mutect2
- PTCHD1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as COSV65062395; called by muse, mutect2, varscan2
- PTCHD4 | c.2438C>T p.S813F | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59794829; called by muse, mutect2
- PTEN | c.86A>C p.Y29S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.879); catalogued as COSV64304290; called by muse, mutect2, varscan2
- PTGER3 | c.1117G>A p.E373K (on ENST00000370932; = p.G373E on NM_198716.2) | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV63392110; called by muse, mutect2, varscan2
- PTGFR | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66116357; called by muse, mutect2, varscan2
- PTPRB | c.3791C>T p.P1264L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54250940; called by muse, mutect2, varscan2
- PTPRC | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV61419376; called by muse, mutect2, varscan2
- PTPRD | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.728); catalogued as COSV61931487; called by muse, mutect2, varscan2
- PTPRK | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.489); catalogued as rs757490289, COSV63888355; called by muse, mutect2, varscan2
- PTPRN2 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV67040947, COSV67057469; called by muse, mutect2, varscan2
- PTPRR | c.1835G>A p.G612E | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1566047072, COSV51744728; called by muse, mutect2, varscan2
- PTPRS | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs724159895, COSV53633933; called by muse, mutect2, varscan2
- PTPRT | c.918G>A p.W306* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV61981219, COSV61988886; called by muse, mutect2, varscan2
- PTPRU | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60535000; called by muse, mutect2, varscan2
- PYROXD2 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 36/48 reads (75%) | catalogued as rs1241774521, COSV65331215; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as rs371900415, COSV99769861; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs569826588, COSV51936971; called by muse, mutect2, varscan2
- RAD9A | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV57237912; called by muse, mutect2, varscan2
- RALGPS1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1189476442, COSV52230298; called by muse, mutect2, varscan2
- RANBP2 | c.7292C>T p.S2431L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.36); catalogued as rs748998622, COSV51700763, COSV99313431; called by mutect2, varscan2
- RARRES1 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs938058778, COSV52963509; called by muse, mutect2, varscan2
- RASGRF2 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs889399240, COSV54122306; called by muse, mutect2, varscan2
- RASGRF2 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.564); catalogued as COSV54137499; called by muse, mutect2, varscan2
- RASGRF2 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as rs151071760, COSV54137508; called by muse, mutect2, varscan2
- RBCK1 | c.1313T>C p.M438T (on ENST00000356286 / NM_031229.4; = p.M396T on NM_006462.6) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV62293159; called by muse, varscan2
- RELN | c.10194G>A p.M3398I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.854); catalogued as COSV59028763; called by muse, mutect2, varscan2
- RERE | c.4118C>T p.P1373L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1364710409, COSV100555700; called by muse, mutect2, varscan2
- RESF1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV57025017; called by muse, mutect2, varscan2
- REV3L | c.672A>G p.I224M | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs1457565874, COSV62622353; called by muse, mutect2, varscan2
- RFFL | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV52073807; called by muse, mutect2, varscan2
- RFTN1 | c.1184A>G p.N395S | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61922416; called by muse, mutect2, varscan2
- RFX6 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 14/18 reads (78%) | catalogued as COSV60588188; called by muse, mutect2, varscan2
- RGS2 | c.302T>C p.L101S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52459665; called by muse, mutect2, varscan2
- RGS7 | c.602G>T p.R201M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58557182; called by muse, mutect2, varscan2
- RGS7BP | c.464-1G>A p.X155_splice | Splice Site (SNP) | VAF 21/56 reads (38%) | catalogued as COSV61836631; called by muse, mutect2, varscan2
- RGS7BP | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 45/54 reads (83%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61836502; called by muse, varscan2
- RGS9 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs145263061, COSV52228669; called by muse, mutect2, varscan2
- RHAG | c.64T>A p.L22I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV57704342, COSV57705932; called by muse, mutect2, varscan2
- RHBDL2 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394337721, COSV56709544; called by muse, mutect2, varscan2
- RNF152 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV57184134; called by muse, mutect2, varscan2
- RNF152 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 42/87 reads (48%) | catalogued as COSV57187590; called by muse, varscan2
- RNF17 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs778361719, COSV55048816; called by muse, mutect2, varscan2
- RNF19B | c.1904C>A p.P635H | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV99331251; called by muse, mutect2, varscan2
- RNF19B | c.1903C>A p.P635T | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.037); catalogued as rs370533666, COSV52387051, COSV52387293; called by muse, mutect2, varscan2
- ROBO2 | c.2893G>A p.A965T | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV59933638; called by muse, mutect2, varscan2
- ROBO2 | c.3997G>A p.G1333R | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59933646; called by muse, mutect2, varscan2
- ROS1 | c.6892G>A p.E2298K | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1451070985, COSV63860351; called by muse, mutect2, varscan2
- RP1 | c.1753G>A p.V585I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV55124556; called by muse, mutect2, varscan2
- RPAP2 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV72509563; called by muse, mutect2, varscan2
- RPGRIP1 | c.2909C>T p.S970F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV52855650; called by muse, mutect2, varscan2
- RPS13 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV57180541; called by muse, varscan2
- RPS6KA6 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53125432; called by muse, mutect2, varscan2
- RPTN | c.2027G>A p.G676E | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.054); catalogued as COSV60168794; called by muse, mutect2, varscan2
- RRAGB | c.745G>A p.E249K (on ENST00000262850 / NM_016656.4; = p.E221K on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as COSV53331186, COSV53331680; called by muse, mutect2, varscan2
- RSPH1 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV52320844; called by muse, mutect2, varscan2
- RTL5 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as COSV65454658; called by muse, mutect2, varscan2
- RTL9 | c.3301G>A p.D1101N | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.822); catalogued as COSV71826173; called by muse, mutect2, varscan2
- RTTN | c.1528T>A p.L510M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV55350592; called by muse, mutect2, varscan2
- RUBCN | c.2341C>T p.L781F | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56372625; called by muse, mutect2, varscan2
- RUNX1T1 | c.1159G>A p.E387K (on ENST00000265814 / NM_001198628.1; = p.E360K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV56147503; called by muse, mutect2, varscan2
- RYR2 | c.14422G>A p.D4808N | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as rs777414943, COSV63707880, COSV63711486; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAA1 | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as rs1339428016, COSV100736521; called by muse, mutect2, varscan2
- SALL2 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1165528874, COSV58105161; called by muse, mutect2, varscan2
- SCAF1 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 18/32 reads (56%) | catalogued as rs1158710132, COSV62182347; called by muse, mutect2, varscan2
- SCAMP3 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV56944054; called by muse, mutect2, varscan2
- SCEL | c.1687G>A p.G563R (on ENST00000349847 / NM_144777.3; = p.G543R on NM_003843.4) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs866414965, COSV62994385; called by muse, mutect2, varscan2
- SCMH1 | c.542C>T p.P181L (on ENST00000326197 / NM_001031694.2; = p.P134L on NM_012236.4) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58239146; called by muse, mutect2, varscan2
- SEC31A | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs747567461, COSV52341196; called by muse, mutect2, varscan2
- SEMA6B | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.762); catalogued as COSV56705606; called by muse, mutect2, varscan2
- SEMG1 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs770619058, COSV54873720; called by muse, mutect2, varscan2
- SERPINB11 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs267605230, COSV66957688; called by muse, mutect2
- SERPIND1 | c.801G>A p.M267I | Missense Mutation (SNP) | VAF 95/210 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53140532; called by muse, mutect2, varscan2
- SEZ6L | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as COSV50680233; called by muse, mutect2, varscan2
- SF1 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1438055254, COSV57115239; called by muse, mutect2, varscan2
- SF3B2 | c.2378C>T p.A793V | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs778566339, COSV57698533; called by muse, mutect2, varscan2
- SFXN3 | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV56521192; called by muse, mutect2, varscan2
- SGTB | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV66818455; called by muse, mutect2, varscan2
- SH2D1A | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs775191468, COSV100758371, COSV63579684; called by muse, mutect2, varscan2
- SHANK2 | c.4060G>A p.E1354K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs374644080; called by muse, mutect2, varscan2
- SI | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52275021; called by muse, mutect2, varscan2
- SLC14A1 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58933759; called by muse, mutect2, varscan2
- SLC15A2 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55200300; called by muse, mutect2
- SLC17A4 | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 56/65 reads (86%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV64955527, COSV64957080; called by muse, mutect2, varscan2
- SLC22A2 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs141405449; called by muse, mutect2, varscan2
- SLC25A12 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 26/33 reads (79%) | catalogued as COSV55536472; called by muse, mutect2, varscan2
- SLC27A5 | c.1295A>G p.Y432C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1453591395, COSV54021543; called by muse, mutect2, varscan2
- SLC27A6 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52486833; called by muse, mutect2, varscan2
- SLC29A4 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs762792716, COSV51876392; called by muse, mutect2, varscan2
- SLC2A4RG | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1248093741, COSV55509634; called by muse, mutect2, varscan2
- SLC35C2 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1329275416, COSV54758251; called by muse, mutect2, varscan2
- SLC38A4 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as COSV56970598; called by muse, mutect2, varscan2
- SLC38A8 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV55309075; called by muse, mutect2, varscan2
- SLC45A1 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV99238542; called by muse, mutect2, varscan2
- SLC6A1 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779431997, COSV55114077; called by muse, mutect2, varscan2
- SLC6A14 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as rs781931614, COSV100903098; called by muse, mutect2, varscan2
- SLC6A14 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV64148371; called by muse, mutect2, varscan2
- SLC6A14 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64148379; called by muse, mutect2, varscan2
- SLC7A3 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as COSV53229008; called by muse, mutect2, varscan2
- SLIT2 | c.3220G>A p.D1074N | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs143782841, COSV56582960; called by muse, mutect2, varscan2
- SLIT3 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV60625645; called by muse, mutect2, varscan2
- SMAD3 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV59288674, COSV59290539; called by muse, mutect2, varscan2
- SMARCA2 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV61811423; called by muse, mutect2, varscan2
- SNAP25 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.075); catalogued as COSV54774996; called by muse, mutect2, varscan2
- SNCAIP | c.2693G>A p.G898E | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs199517639, COSV54419306; called by muse, mutect2, varscan2
- SNRPB | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.532); catalogued as COSV60016374; called by muse, mutect2, varscan2
- SORCS3 | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.901); catalogued as COSV63821416; called by muse, mutect2, varscan2
- SORL1 | c.479G>A p.S160N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs770587574, COSV52761037, COSV99492791; called by muse, mutect2, varscan2
- SORL1 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs867605753, COSV52755303; called by muse, mutect2, varscan2
- SOWAHB | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57554286; called by muse, mutect2, varscan2
- SPAG16 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59119936; called by muse, mutect2, varscan2
- SPAG17 | c.5300A>C p.Q1767P | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60466285; called by muse, mutect2, varscan2
- SPAM1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.082); catalogued as rs778526503, COSV56144838; called by muse, mutect2, varscan2
673 further variants in this file (175 protein-altering or splice-affecting, 467 silent, 31 other) are not listed here.
